Surgical pathology report (de-identified scan), TCGA case TCGA-FV-A3R2, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-FV-A3R2-01A (Primary Tumor).

Collected:
Received:
Reported:

SPECIMEN INFORMATION

Accession #:
Acct / Reg #:

SURGICAL PATHOLOGY REPORT

DIAGNOSIS

DIAGNOSIS:

A. Mass, liver, excision:

Hepatocellular carcinoma, 8.0 x 6.0 x 5.0 cm.

Tumor approaches to within 0.5 cm of the inked surgical margin, but the inked margins of resection appear free of malignancy.
Background liver with chronic portal inflammation - no evidence of cirrhosis.

B. Vermiform appendix, appendectomy:

Benign appendix showing no evidence of appendicitis or malignancy.

Electronic Signature

COMMENTS:

QC Pathologist -

CLINICAL INFORMATION

CLINICAL HISTORY:

Preoperative Diagnosis: Left lateral hepatic lobe for hepctoma.

Postoperative Diagnosis:

Symptoms/Radiologic Findings:

SPECIMENS:

A. Hepatoma

B. Appendix

SPECIMEN DATA

GROSS DESCRIPTION:

A. Container A is labeled [redacted] and consists of a 270 gm portion of liver tissue, 10.5 x 10.0 x 6.0 cm in greatest dimension. The capsule is orange-brown with a tan-yellow, firm, nodular appearance. The surgical margin has been inked. Sectioning reveals a tan-brown, firm parenchyma with a nutmeg appearance. A tan-yellow, poorly circumscribed, lobular mass is found, 8.0 x 6.0 x 5.0 cm in greatest dimension. This mass extends to within 0.5 cm of the surgical margin and replaces approximately 75% of the parenchyma. Multiple samples have been submitted for genomic studies in seven cassettes. Representative samples submitted in eight cassettes labeled '1' and are designated as follows: Margin submitted in cassettes 1 and 2; lesions 3 through 6; normal hepatic tissue 7 and 8.

B. Container B is labeled [redacted] and consists of a tan-pink, vermiform appendix, 6.0 cm in length and up to 0.7 cm in diameter. The serosal surface displays multiple adhesions as well as an abundant amount of adhered tan-yellow, lobular adipose tissue. Sectioning reveals a pinpoint lumen. Representative samples are submitted in one cassette labeled [redacted].

1CD-0-3

Carcinoma, hepatocellular, NOS

817013

Site: liver ca2.0

3-30-12

RD

QUAIFIED DISQUALIFIED

3/31/12 3/2/12

Source: NCI Genomic Data Commons file 834e344b-9ebd-47c6-98d9-1d03cae30e1c (TCGA-FV-A3R2.6F330991-CD7E-4387-AFE8-B9C6C8D98396.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).